Surgical pathology report (de-identified scan), TCGA case TCGA-68-A59J, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Cleveland Clinic, specimen TCGA-68-A59J-01A (Primary Tumor).

[page 1 of 2]
Qual/Synchronous Primary	Noted	
Reviewer Initials	R6	Date Reviewed: 11/19/12

ICD-O-3

Carcinoma, Squamous Cell NOS

8070/3

Site: R Lung, Lower Lobe

C34.3

gnd 1/7/13

SURGICAL PATHOLOGY REPORT

Patient Age/Sex F

SPECIMEN SUBMITTED:

Part A: SUPERIOR SEGMENT WITH
WEDGE OF LATERAL BASILAR SEGMENT

Part B: R12

Part C: R9

Part D: R4

Final Diagnosis

1. Right lung, lower lobe, superior segmentectomy and lateral basilar segment wedge resection (A)
- Invasive poorly differentiated squamous cell carcinoma (see comment).

2. Lymph nodes, R12, R9, R4, excision (B-D) - Lymph nodes, negative for neoplasm.

Diagnosis Comment:

SPECIMEN: Right lower lobe.

PROCEDURE: superior segmentectomy and lateral basilar segment wedge excision

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Lower lobe

TUMOR SIZE: 4.9 x 4.8 x 3.5 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: Grade 3 poorly differentiation

VISCERAL PLEURAL INVASION: pending Movat stains; addendum report will follow.

TUMOR EXTENSION: Not identified

MARGINS:

- Bronchial margin: negative

- Vascular Margin negative

- Parenchymal margin: negative

- Parietal pleural margin: Not applicable

- Chest wall margin: Not applicable

- Other attached tissue margin: Not applicable

TREATMENT EFFECT: Not applicable

TUMOR ASSOCIATED ATELECTASIS OR OBSTRUCTIVE PNEUMONITIS: Negative

LYMPH-VASCULAR INVASION: Not identified

LYMPH NODES: negative

PATHOLOGIC STAGING: p stage IB (T2a N0 MX)

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Non-small cell carcinoma. Bronchial margin and staple line margin negative for tumor

Clinical Diagnosis:

RIGHT LOWER LOBE MASS-SQUAMOUS CELL CA

Gross Description:

A. Received fresh for frozen diagnosis labeled "superior segment with wedge of lateral basilar segment" is a wedge of lung tissue measuring 12.7 x 7.5 x 3.4 cm, and weighing 197 grams. The parenchymal line of resection is inked blue. A tan firm lobulated mass with necrosis is present within the lung parenchyma measuring 4.9 x 4.8 x 3.5 cm, extending to the pleural surface and located 2.7 cm from the bronchial margin and 0.9 cm from the parenchymal margin. Focal anthracotic pigment is identified. The remaining lung parenchyma is red-brown and unremarkable. Representative sections are submitted as follows: A1 frozen section bronchial margin, A2 frozen section of mass with inked parenchymal line of resection, A3-A8 mass (A3-A4 with pleural surface, A5 with parenchymal line of resection) A9 vascular margin, A10 non-tumoral lung, A11 possible lymph node tissue.

B. Received fresh labeled "R12" are twelve red-black to gray nodules ranging in size from 0.4-2.5 cm in greatest dimension. The segments are totally submitted in formalin as follows: B1 six nodules, B2 four nodules, B3 two nodules.

C. Received fresh labeled "R9" is a segment of black-tan soft tissue measuring 0.5 x 0.2 x 0.2 cm. The specimen is totally submitted in formalin in C1.

D. Received fresh labeled "R4" are four segments of yellow-tan to red soft tissue ranging in size from 0.5-1.5 cm in greatest dimension. The segments are totally submitted in formalin in D1.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file c1d8fcfd-1b20-4ca8-969f-e2bfe276bcf4 (TCGA-68-A59J.629F9E80-0846-48A6-A872-5250D66BD0F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).